Somatic mutation profile of tumor specimen TCGA-69-7979-01A (aliquot TCGA-69-7979-01A-11D-2184-08) from TCGA case TCGA-69-7979, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.7 years (26,180 days).
Specimen TCGA-69-7979-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bb37741-dfe9-4b77-93da-4a20792fe795.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-69-7979-10A (Blood Derived Normal), aliquot TCGA-69-7979-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3721df1-653c-408e-b3fa-b7c11c1e3413

The open-access MAF lists 1,593 somatic variants for this specimen: 1,235 protein-altering or splice-affecting, 325 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,050, Silent 325, Nonsense Mutation 90, Splice Site 38, Frame Shift Del 27, RNA 16, Splice Region 13, Frame Shift Ins 9, Intron 8, 3'UTR 7, Translation Start Site 3, In Frame Del 2.

Variants (750 of 1,593; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLA | c.708G>T p.W236C | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869312386, CM960769, COSV54509978; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.407_424del p.Q136_C141del | In Frame Del (DEL) | VAF 41/77 reads (53%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AADACL2 | c.725C>A p.T242N | Missense Mutation (SNP) | VAF 86/367 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV62931358; called by muse, mutect2, varscan2
- AASDH | c.2729A>G p.H910R | Missense Mutation (SNP) | VAF 150/175 reads (86%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV52708307; called by muse, mutect2, varscan2
- ABCA2 | c.3322G>T p.D1108Y (on ENST00000614293; = p.D1078Y on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/193 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55803211, COSV55803778; called by muse, mutect2, varscan2
- ABCA7 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV54033280; called by muse, mutect2, varscan2
- ABCB1 | c.3827G>C p.G1276A | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV55956674; called by muse, mutect2, varscan2
- ABCB5 | c.3004A>T p.S1002C (on ENST00000404938 / NM_001163941.2; = p.S557C on NM_178559.6) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV51714748; called by muse, mutect2, varscan2
- ABHD3 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.428); catalogued as COSV56677358; called by muse, mutect2
- AC097636.1 | c.85C>A p.H29N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV71309566; called by muse, varscan2
- ACACB | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.286); catalogued as COSV58139897; called by muse, mutect2, varscan2
- ACACB | c.2946G>T p.Q982H | Missense Mutation (SNP) | VAF 66/263 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.217); catalogued as rs765175424, COSV58139909, COSV58147409; called by muse, mutect2, varscan2
- ACACB | c.4002-2A>G p.X1334_splice | Splice Site (SNP) | VAF 27/103 reads (26%) | catalogued as COSV58139915; called by muse, mutect2, varscan2
- ACAD11 | c.1786G>T p.G596* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as COSV53898963; called by muse, mutect2, varscan2
- ACAN | c.6892G>T p.G2298* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | catalogued as COSV61364619; called by muse, mutect2, varscan2
- ACER2 | c.109-1G>T p.X37_splice | Splice Site (SNP) | VAF 44/125 reads (35%) | catalogued as COSV61821102; called by muse, mutect2, varscan2
- ACSBG1 | c.831T>A p.C277* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV51908466; called by muse, mutect2, varscan2
- ADAM19 | c.906G>T p.T302= | Splice Region (SNP) | VAF 32/58 reads (55%) | catalogued as COSV57434432; called by muse, mutect2, varscan2
- ADAM28 | c.368C>G p.T123R | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV56102696; called by muse, mutect2, varscan2
- ADAMTS1 | c.2360C>A p.T787N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV53171719; called by muse, mutect2, varscan2
- ADAMTS10 | c.1373C>A p.P458H | Missense Mutation (SNP) | VAF 181/250 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54356793; called by muse, mutect2, varscan2
- ADAMTS12 | c.3734C>G p.A1245G | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV61269771; called by muse, mutect2
- ADAMTS12 | c.3086C>A p.P1029H | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV61269777; called by muse, mutect2, varscan2
- ADAMTS12 | c.3084G>T p.R1028S | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61269782; called by muse, mutect2, varscan2
- ADAMTS15 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.202); catalogued as COSV100143089; called by muse, mutect2, varscan2
- ADAMTS16 | c.244C>G p.H82D | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.096); catalogued as COSV56997823; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4597C>A p.P1533T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65878404; called by muse, mutect2, varscan2
- ADARB2 | c.1923G>T p.W641C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67182499; called by muse, mutect2, varscan2
- ADCY1 | c.1899G>T p.Q633H | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV52038444; called by muse, mutect2, varscan2
- ADCY5 | c.3310A>T p.I1104F | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV59200774; called by mutect2, varscan2
- ADCY8 | c.3182G>T p.C1061F | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV53916837; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.131T>G p.L44R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.024); catalogued as COSV100416179, COSV99061923; called by muse, mutect2, varscan2
- ADD2 | c.868C>A p.H290N | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52465545; called by muse, mutect2, varscan2
- ADGRA1 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101192629; called by muse, mutect2, varscan2
- ADGRB2 | c.2782C>A p.L928M | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.535); catalogued as COSV99925678; called by muse, mutect2, varscan2
- ADGRG4 | c.9050G>T p.R3017L | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV54958141, COSV54961691; called by muse, mutect2, varscan2
- ADGRL2 | c.519G>T p.M173I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV54676893; called by muse, mutect2, varscan2
- ADGRL3 | c.1992C>A p.D664E (on ENST00000506720 / NM_001322402.2; = p.D596E on NM_015236.6) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs759611747, COSV63368467; called by muse, mutect2, varscan2
- ADGRL3 | c.2839G>C p.V947L (on ENST00000506720 / NM_001322402.2; = p.V879L on NM_015236.6) | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); catalogued as COSV72231244, COSV72231859, COSV72232087; called by muse, mutect2, varscan2
- ADGRL4 | c.608A>T p.Q203L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV66063162; called by muse, mutect2, varscan2
- ADGRV1 | c.1105G>T p.G369* | Nonsense Mutation (SNP) | VAF 50/88 reads (57%) | catalogued as COSV67990075; called by muse, mutect2, varscan2
- ADPRH | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV63695394; called by muse, mutect2, varscan2
- ADRA1A | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.3); catalogued as COSV52369416; called by muse, mutect2, varscan2
- ADRA2A | c.727C>A p.R243S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1172690699, COSV99701459; called by muse, mutect2
- AFF2 | c.1557G>T p.E519D | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99661872; called by muse, mutect2, varscan2
- AFF2 | c.1557+1G>T p.X519_splice | Splice Site (SNP) | VAF 17/153 reads (11%) | catalogued as COSV99661903; called by muse, mutect2, varscan2
- AGBL4 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100885294; called by muse, mutect2, varscan2
- AGMO | c.666G>T p.R222S | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs750140675, COSV61117642; called by muse, mutect2, varscan2
- AGPAT3 | c.767+1G>A p.X256_splice | Splice Site (SNP) | VAF 32/103 reads (31%) | catalogued as COSV52372164; called by muse, mutect2, varscan2
- AGPAT4 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100211229, COSV57248272; called by muse, mutect2, varscan2
- AHI1 | c.1786C>A p.R596S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99661956; called by muse, mutect2, varscan2
- AHNAK2 | c.11450C>G p.A3817G | Missense Mutation (SNP) | VAF 81/612 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV60921943; called by muse, mutect2, varscan2
- AHNAK2 | c.10685C>T p.P3562L | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372078377; called by muse, mutect2
- AIM2 | c.640C>G p.R214G | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV104426653, COSV63700735; called by muse, mutect2, varscan2
- AKIRIN2 | c.361A>T p.S121C | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as COSV57636988; called by muse, mutect2, varscan2
- AKR1E2 | c.136G>T p.V46F | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53630991; called by muse, mutect2, varscan2
- ALB | c.1786-2A>T p.X596_splice | Splice Site (SNP) | VAF 5/34 reads (15%) | catalogued as COSV55740108; called by muse, mutect2, varscan2
- ALDH1L1 | c.109G>T p.G37* | Nonsense Mutation (SNP) | VAF 79/114 reads (69%) | catalogued as COSV56416597; called by muse, mutect2, varscan2
- ALOX12B | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 100/152 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59874486; called by mutect2, varscan2
- ALS2 | c.2517G>T p.L839F | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.515); catalogued as COSV51889635; called by muse, mutect2, varscan2
- AMER1 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV57658314; called by muse, mutect2, varscan2
- AMER1 | c.1152G>T p.E384D | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); catalogued as COSV100365274; called by muse, mutect2, varscan2
- AMER1 | c.288C>A p.H96Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57663755; called by muse, mutect2, varscan2
- AMOT | c.1731G>T p.Q577H (on ENST00000371959 / NM_001113490.1; = p.Q168H on NM_133265.3) | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV59065966; called by muse, mutect2, varscan2
- AMY2B | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs759212934, COSV63716131; called by muse, mutect2, varscan2
- ANGPT4 | c.293C>G p.T98R | Missense Mutation (SNP) | VAF 113/258 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67922253; called by muse, mutect2, varscan2
- ANK1 | c.2023G>T p.V675L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV55887415; called by muse, mutect2, varscan2
- ANKK1 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); catalogued as rs368483324, COSV58271006; called by muse, mutect2, varscan2
- ANKRD30A | c.974C>A p.P325H (on ENST00000611781; = p.P269H on NM_052997.2) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV64615348, COSV64616134; called by muse, mutect2, varscan2
- ANKRD45 | c.386T>A p.L129Q | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60961858; called by muse, mutect2, varscan2
- ANO4 | c.1441C>T p.R481W (on ENST00000392977 / NM_001286615.2; = p.R446W on NM_178826.4) | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs765804915, COSV54602170; called by muse, mutect2, varscan2
- APBA3 | c.1145A>T p.D382V | Missense Mutation (SNP) | VAF 49/64 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53664110; called by muse, mutect2, varscan2
- APBB1IP | c.313A>T p.S105C | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.43); catalogued as rs1012939575, COSV63303216; called by muse, mutect2, varscan2
- APCS | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54818702, COSV54818813; called by muse, mutect2, varscan2
- APOA5 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.76); catalogued as COSV57063967; called by muse, mutect2, varscan2
- APRT | c.363G>C p.Q121H | Missense Mutation (SNP) | VAF 88/161 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs747315064, COSV51938882; called by muse, mutect2, varscan2
- ARAP3 | c.2218G>T p.V740L | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV53352408; called by muse, mutect2, varscan2
- ARHGAP18 | c.1807G>T p.D603Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63765247; called by muse, mutect2, varscan2
- ARHGAP19 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as rs1192518173, COSV57394308; called by muse, mutect2, varscan2
- ARHGAP30 | c.596T>G p.V199G | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63517738; called by muse, mutect2, varscan2
- ARHGAP31 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1305339961, COSV51796095; called by muse, mutect2, varscan2
- ARHGAP33 | c.745C>G p.R249G | Missense Mutation (SNP) | VAF 73/365 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV50134323; called by muse, mutect2, varscan2
- ARHGEF3 | c.758G>T p.W253L | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV56329618; called by muse, mutect2, varscan2
- ARL11 | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV56291658, COSV99949178; called by muse, mutect2, varscan2
- ARMT1 | c.946G>T p.G316W | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66178833; called by muse, mutect2, varscan2
- ARNT2 | c.847A>G p.T283A | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57587915; called by muse, mutect2, varscan2
- ASAP2 | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV55634932; called by mutect2, varscan2
- ASCC3 | c.3211G>C p.D1071H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV61231001; called by muse, mutect2, varscan2
- ASH1L | c.7181A>T p.Y2394F (on ENST00000368346 / NM_001366177.2; = p.Y2389F on NM_018489.3) | Missense Mutation (SNP) | VAF 115/566 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.202); catalogued as rs753343387, COSV64210607; called by muse, mutect2, varscan2
- ASTN1 | c.3516G>T p.E1172D | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV62500796; called by muse, mutect2, varscan2
- ASTN2 | c.487C>A p.Q163K | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV57796728; called by muse, mutect2, varscan2
- ATAD2 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV54883721; called by muse, mutect2
- ATF6 | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs374129058, COSV63408613; called by muse, mutect2, varscan2
- ATM | c.3154-1G>T p.X1052_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV53753080, COSV53757872; called by muse, mutect2, varscan2
- ATOH1 | c.281C>A p.A94E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); catalogued as rs761216588, COSV60038295; called by muse, mutect2, varscan2
- ATP10D | c.2187C>G p.D729E | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56710152; called by muse, mutect2, varscan2
- ATP13A5 | c.1498G>T p.G500W | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100664724, COSV60872672; called by muse, mutect2
- ATP13A5 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.673); catalogued as COSV100664726, COSV60871269; called by muse, mutect2
- ATP2A1 | c.1847A>T p.D616V | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.066); catalogued as COSV62870175; called by muse, mutect2, varscan2
- ATP2A3 | c.137G>C p.G46A | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV59231848, COSV99989833; called by muse, mutect2, varscan2
- ATP2B3 | c.2119G>T p.D707Y | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54854471; called by muse, mutect2, varscan2
- ATRNL1 | c.4097G>A p.R1366Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); catalogued as rs781857655, COSV58099412; called by muse, mutect2, varscan2
- ATXN2 | c.2851C>T p.H951Y (on ENST00000550104; = p.H791Y on NM_002973.4) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.968); catalogued as COSV66484669; called by muse, mutect2, varscan2
- AVPR2 | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as CD982481, COSV61686570; called by muse, mutect2, varscan2
- AXIN1 | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.414); catalogued as rs150141520, COSV51989904; called by muse, mutect2, varscan2
- B3GNT7 | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV55007050; called by muse, mutect2, varscan2
- B4GALNT3 | c.786+1G>T p.X262_splice | Splice Site (SNP) | VAF 20/44 reads (45%) | catalogued as COSV56755254, COSV56756182; called by muse, mutect2, varscan2
- BAMBI | c.782G>T p.*261Lext*5 | Nonstop Mutation (SNP) | VAF 30/99 reads (30%) | catalogued as COSV65003223; called by muse, mutect2, varscan2
- BAZ1B | c.1116G>C p.M372I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59992563; called by muse, mutect2, varscan2
- BBX | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57889245; called by muse, mutect2, varscan2
- BBX | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as COSV57889270; called by muse, mutect2, varscan2
- BCAN | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV100227848; called by muse, mutect2, varscan2
- BCHE | c.695T>G p.V232G | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM147422, COSV52259411; called by muse, mutect2, varscan2
- BCKDHB | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 46/334 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV57515604; called by muse, mutect2, varscan2
- BCO2 | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.593); catalogued as COSV63064163; called by muse, mutect2
- BEST3 | c.1398G>T p.M466I | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV58303181; called by muse, mutect2, varscan2
- BMS1 | c.2769+1G>T p.X923_splice | Splice Site (SNP) | VAF 34/68 reads (50%) | catalogued as COSV65734675; called by muse, mutect2, varscan2
- BNC2 | c.2306A>T p.Q769L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV101032121; called by muse, mutect2, varscan2
- BNC2 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as COSV66151960; called by muse, mutect2, varscan2
- BOLL | c.497G>T p.S166I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.442); catalogued as COSV56575054; called by muse, mutect2, varscan2
- BPIFB6 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62754824; called by muse, mutect2, varscan2
- BRD2 | c.383G>C p.R128T | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV66373989; called by muse, mutect2, varscan2
- BRINP3 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66531766; called by muse, mutect2, varscan2
- BRS3 | c.325C>A p.L109I | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.158); catalogued as COSV65711188; called by muse, mutect2, varscan2
- C19orf25 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs748515428, COSV56300064; called by muse, mutect2, varscan2
- C1orf112 | c.1214G>A p.S405N | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.115); catalogued as rs1558077410, COSV53680762; called by muse, mutect2, varscan2
- C20orf96 | c.701A>G p.Q234R (on ENST00000360321 / NM_153269.3; = p.Q233R on NM_080571.1) | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); catalogued as COSV64404051; called by muse, mutect2
- C2CD3 | c.2836A>T p.S946C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58095735; called by muse, mutect2, varscan2
- C2orf78 | c.1337C>G p.T446R | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV68518409; called by muse, mutect2, varscan2
- C3orf20 | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53787098; called by muse, mutect2, varscan2
- C4orf50 | c.685C>A p.P229T (on ENST00000324058; = p.P1461T on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as COSV60689678; called by muse, mutect2, varscan2
- C5orf49 | c.210G>T p.L70F | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67708988; called by muse, mutect2, varscan2
- C9 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV54678927, COSV54680338; called by muse, mutect2, varscan2
- CA3 | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.993); catalogued as COSV53410488; called by muse, mutect2, varscan2
- CACNA1A | c.2516C>A p.T839N | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as COSV64204544; called by muse, mutect2, varscan2
- CACNA1C | c.6191G>T p.G2064V (on ENST00000399634 / NM_001167625.1; = p.G1993V on NM_000719.7) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.069); catalogued as COSV59744158; called by muse, mutect2, varscan2
- CACNA1E | c.2645C>A p.P882Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV62405850; called by muse, mutect2, varscan2
- CACNA1E | c.4169G>A p.G1390D | Missense Mutation (SNP) | VAF 19/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62405856; called by muse, mutect2
- CACNA1F | c.2362G>T p.G788C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV59905645; called by muse, mutect2, varscan2
- CACNA1S | c.258+1G>T p.X86_splice | Splice Site (SNP) | VAF 8/134 reads (6%) | catalogued as COSV62941659; called by muse, mutect2
- CACNB4 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52398240; called by muse, mutect2, varscan2
- CALCR | c.1252G>T p.V418L (on ENST00000649521 / NM_001164737.2; = p.V402L on NM_001742.4) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64007153, COSV64009997; called by muse, mutect2, varscan2
- CAMTA2 | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61836402; called by muse, mutect2, varscan2
- CAPN11 | c.2153A>T p.D718V | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67238495; called by muse, mutect2, varscan2
- CAPN12 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); catalogued as rs780134495, COSV61017159; called by mutect2, varscan2
- CAPN6 | c.575C>A p.T192K | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV60694125, COSV60696047; called by muse, mutect2, varscan2
- CAPS | c.89T>C p.F30S | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50382382; called by muse, mutect2
- CARD11 | c.1738G>T p.D580Y | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV62756012; called by muse, mutect2, varscan2
- CASS4 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV64387401; called by muse, mutect2
- CCDC180 | c.3854A>T p.N1285I | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.116); catalogued as COSV63832539; called by muse, mutect2, varscan2
- CCDC74A | c.1007G>T p.C336F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54608121; called by muse, mutect2, varscan2
- CCDC77 | c.414G>T p.R138S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV53474153; called by muse, mutect2, varscan2
- CCDC81 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 56/258 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV53579895; called by muse, mutect2, varscan2
- CCT6B | c.585G>C p.E195D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV58489934; called by muse, mutect2, varscan2
- CCT6B | c.499G>T p.V167F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.396); catalogued as COSV58490370; called by muse, mutect2, varscan2
- CD109 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 115/164 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54653007; called by muse, mutect2, varscan2
- CD226 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1451379862, COSV54614116; called by muse, mutect2, varscan2
- CD244 | c.685C>G p.P229A (on ENST00000368033 / NM_001166663.2; = p.P224A on NM_016382.4) | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.099); catalogued as COSV59238277, COSV59239600; called by muse, mutect2, varscan2
- CD248 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60937191; called by muse, mutect2, varscan2
- CD2BP2 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.341); catalogued as COSV59769297, COSV99977037; called by muse, mutect2, varscan2
- CDC42BPA | c.1937G>T p.R646M | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62015513; called by muse, mutect2, varscan2
- CDH18 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56940536; called by muse, mutect2, varscan2
- CDH4 | c.1561C>A p.P521T | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); catalogued as COSV64663931; called by muse, mutect2, varscan2
- CDH6 | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 30/349 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV54074114; called by muse, mutect2
- CDH7 | c.539C>G p.A180G | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as COSV59889568; called by muse, mutect2, varscan2
- CDH7 | c.2167G>T p.G723C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100541279, COSV59889579, COSV99064586; called by muse, mutect2, varscan2
- CDK13 | c.2716G>T p.E906* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV51703082, COSV99476032; called by muse, mutect2, varscan2
- CDYL | c.654G>T p.E218D (on ENST00000328908 / NM_001368125.1; = p.E164D on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV59360651; called by muse, mutect2, varscan2
- CELF5 | c.594G>T p.Q198H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV53013250; called by muse, mutect2, varscan2
- CENPF | c.6442G>T p.E2148* | Nonsense Mutation (SNP) | VAF 39/87 reads (45%) | catalogued as COSV65276670; called by muse, mutect2, varscan2
- CEP170 | c.309G>T p.M103I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.329); catalogued as COSV100316387; called by muse, mutect2
- CES5A | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV51868462; called by muse, mutect2, varscan2
- CFAP20DC | c.2239G>T p.D747Y (on ENST00000482387 / NM_001351530.2; = p.D496Y on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55916086, COSV55923650; called by muse, mutect2, varscan2
- CFAP46 | c.6130G>T p.E2044* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV54155444, COSV99585233; called by muse, mutect2, varscan2
- CFAP70 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.026); catalogued as COSV60285110; called by muse, mutect2, varscan2
- CFHR5 | c.1697C>G p.P566R | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56824533; called by muse, mutect2, varscan2
- CHD3 | c.2348A>C p.H783P | Missense Mutation (SNP) | VAF 127/184 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57877683; called by muse, mutect2, varscan2
- CHDH | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs763169785, COSV59458735; called by muse, mutect2, varscan2
- CHIT1 | c.460C>A p.R154S | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.523); catalogued as COSV55148192, COSV99705154; called by muse, varscan2
- CHM | c.1853G>T p.G618V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV63303018; called by muse, mutect2, varscan2
- CHMP4C | c.651G>T p.R217S | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV51927204, COSV51927919; called by muse, mutect2, varscan2
- CHN2 | c.992-1G>A p.X331_splice | Splice Site (SNP) | VAF 20/94 reads (21%) | catalogued as COSV56097058; called by muse, mutect2, varscan2
- CHRD | c.2454G>T p.G818= | Splice Region (SNP) | VAF 9/28 reads (32%) | catalogued as COSV52610196; called by muse, mutect2
- CHRDL1 | c.385C>T p.Q129* (on ENST00000372045; = p.Q135* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 50/330 reads (15%) | catalogued as COSV54326504; called by muse, mutect2, varscan2
- CHSY3 | c.1843G>T p.G615W | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV59281879; called by muse, mutect2, varscan2
- CKAP5 | c.13A>T p.S5C | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56370795; called by muse, mutect2, varscan2
- CLCA4 | c.2518C>A p.H840N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV65284325; called by muse, mutect2, varscan2
- CLDN10 | c.183C>A p.C61* | Nonsense Mutation (SNP) | VAF 16/200 reads (8%) | catalogued as COSV65297450, COSV65298439; called by muse, mutect2
- CLDN25 | c.431C>A p.T144K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV71620455; called by muse, mutect2, varscan2
- CLEC16A | c.43A>T p.K15* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV59328846; called by muse, mutect2, varscan2
- CLK2 | c.544G>T p.D182Y (on ENST00000368361 / NM_001294339.2; = p.D181Y on NM_003993.4) | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62877718; called by muse, mutect2, varscan2
- CLNK | c.1242C>A p.H414Q | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV57018122; called by muse, mutect2, varscan2
- CLNK | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57018143; called by muse, mutect2, varscan2
- CLTA | c.229G>T p.G77* | Nonsense Mutation (SNP) | VAF 59/341 reads (17%) | catalogued as COSV54255201; called by muse, mutect2, varscan2
- CMTR2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs147189785, COSV57603952; called by muse, mutect2, varscan2
- CNNM4 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 19/123 reads (15%) | catalogued as COSV65661516; called by muse, mutect2, varscan2
- CNNM4 | c.1291G>C p.D431H | Missense Mutation (SNP) | VAF 69/330 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65661519; called by muse, mutect2, varscan2
- CNTNAP2 | c.3851G>T p.R1284L | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV62198017, COSV62217961; called by muse, mutect2, varscan2
- CNTNAP4 | c.3854C>G p.A1285G | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.416); catalogued as COSV56690733; called by muse, mutect2
- CNTNAP5 | c.58C>A p.H20N | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV101420761, COSV70482627; called by muse, mutect2, varscan2
- CNTNAP5 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.685); catalogued as COSV70497275, COSV70521065; called by muse, mutect2
- COCH | c.452C>T p.S151L (on ENST00000216361 / NM_001347720.1; = p.S86L on NM_004086.3) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs749386539, COSV53551823; called by muse, mutect2, varscan2
- COL1A1 | c.651G>T p.M217I | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.922); catalogued as COSV56807341; called by muse, mutect2, varscan2
- COL1A2 | c.2026G>T p.G676C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as CM011307, COSV51954232; called by muse, mutect2, varscan2
- COL23A1 | c.840G>A p.G280= | Splice Region (SNP) | VAF 21/35 reads (60%) | catalogued as rs1026603251, COSV66793812; called by muse, mutect2, varscan2
- COL24A1 | c.4856C>T p.T1619I | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.679); catalogued as COSV65309616; called by muse, mutect2, varscan2
- COL3A1 | c.2942G>A p.G981E | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58593043; called by muse, mutect2, varscan2
- COL4A1 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 967/1904 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65428511; called by muse, mutect2, varscan2
- COL4A5 | c.729G>T p.Q243H | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as COSV60366178; called by muse, mutect2, varscan2
- COL5A2 | c.2150G>T p.G717V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66411736; called by muse, mutect2, varscan2
- COL5A2 | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66411739; called by muse, mutect2, varscan2
- COL5A3 | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53410420; called by muse, mutect2, varscan2
- COL6A2 | c.1111G>T p.G371C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.416); catalogued as COSV56009459, COSV56010692; called by muse, mutect2, varscan2
- COL6A6 | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV62030590; called by muse, mutect2
- COL6A6 | c.2887A>T p.S963C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV62030605; called by muse, mutect2, varscan2
- COL8A2 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV57442564; called by muse, mutect2, varscan2
- COL9A1 | c.876+1G>A p.X292_splice | Splice Site (SNP) | VAF 20/52 reads (38%) | catalogued as COSV57887947; called by mutect2, varscan2
- COPA | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54105841; called by muse, mutect2, varscan2
- COQ4 | c.203-1G>T p.X68_splice | Splice Site (SNP) | VAF 22/61 reads (36%) | catalogued as COSV55957563; called by muse, mutect2, varscan2
- CPA3 | c.417G>T p.M139I | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs770652989, COSV56046144, COSV99936619; called by muse, mutect2, varscan2
- CPSF2 | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs769975028, COSV54099281; called by muse, mutect2, varscan2
- CPXCR1 | c.421C>A p.P141T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV52162454; called by muse, mutect2, varscan2
- CRABP1 | c.328T>A p.W110R | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55116053; called by muse, mutect2, varscan2
- CRACD | c.3607C>A p.P1203T | Missense Mutation (SNP) | VAF 590/752 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51726125; called by muse, mutect2, varscan2
- CRCP | c.177del p.R59Sfs*15 | Frame Shift Del (DEL) | VAF 19/170 reads (11%) | catalogued as COSV58536083; called by mutect2, pindel, varscan2
- CROCC | c.5414G>T p.R1805L | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.296); catalogued as COSV65003924; called by muse, mutect2, varscan2
- CRY2 | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs775759503, COSV69888813; called by muse, mutect2, varscan2
- CSE1L | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53703329; called by muse, mutect2, varscan2
- CSMD2 | c.1723G>T p.V575L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as rs200557124, COSV53933803; called by muse, mutect2, varscan2
- CSMD3 | c.2534G>T p.R845L (on ENST00000297405 / NM_001363185.1; = p.R741L on NM_052900.3) | Missense Mutation (SNP) | VAF 95/161 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754786650, COSV52123877, COSV52243892; called by muse, mutect2, varscan2
- CSN2 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as rs1003669682, COSV61992393; called by muse, mutect2, varscan2
- CSPG4 | c.6197C>A p.T2066N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV57898501; called by muse, mutect2, varscan2
- CSPG4 | c.3413C>T p.P1138L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.527); catalogued as COSV57898517; called by muse, mutect2, varscan2
- CSRNP2 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.424); catalogued as COSV57334791; called by muse, mutect2, varscan2
- CST4 | c.338A>C p.Q113P | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV54150023; called by muse, mutect2, varscan2
- CST9 | c.361C>A p.L121M | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV65402798; called by muse, mutect2, varscan2
- CSTF1 | c.1037-1G>T p.X346_splice | Splice Site (SNP) | VAF 12/120 reads (10%) | catalogued as COSV53859477; called by muse, mutect2, varscan2
- CTIF | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV56487481; called by muse, mutect2, varscan2
- CTNNA3 | c.1606G>T p.A536S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.525); catalogued as COSV65602677; called by muse, mutect2, varscan2
- CTNNB1 | c.984G>T p.M328I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.061); catalogued as COSV62708666; called by muse, mutect2, varscan2
- CTSG | c.742C>A p.L248M | Missense Mutation (SNP) | VAF 77/276 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.359); catalogued as COSV53535382; called by muse, mutect2, varscan2
- CTSL | c.556G>C p.A186P | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV58246810; called by muse, mutect2, varscan2
- CUBN | c.8566G>A p.G2856S | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs371139445; called by muse, mutect2, varscan2
- CUL1 | c.368G>T p.W123L | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100296417; called by muse, mutect2, varscan2
- CUL1 | c.369G>T p.W123C | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100296419; called by muse, mutect2, varscan2
- DAB2 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV57916561; called by muse, varscan2
- DACH1 | c.934C>A p.L312I | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57507167, COSV57509798; called by muse, mutect2, varscan2
- DBF4 | c.466A>T p.N156Y | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV55997922; called by muse, varscan2
- DCAF12L2 | c.1178C>A p.S393Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.543); catalogued as COSV63583013; called by mutect2, varscan2
- DCAF13 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.345); catalogued as COSV52573070; called by muse, mutect2, varscan2
- DCAF4L2 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 78/144 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60476386, COSV60476821; called by muse, varscan2
- DCAF6 | c.2290G>T p.V764L (on ENST00000312263 / NM_001349778.1; = p.V784L on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100393900; called by muse, mutect2, varscan2
- DCDC1 | c.3075G>C p.R1025S (on ENST00000597505 / NM_001367979.1; = p.R132S on NM_020869.3) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.027); catalogued as COSV60309098; called by muse, mutect2, varscan2
- DCT | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 53/841 reads (6%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.557); catalogued as COSV65470031; called by muse, mutect2
- DCX | c.940C>A p.Q314K | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100576175; called by muse, mutect2, varscan2
- DDX31 | c.1339G>T p.D447Y | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV60137709; called by muse, mutect2, varscan2
- DEFB113 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs868598053, COSV67143245, COSV67143452; called by muse, mutect2, varscan2
- DENND2A | c.2377G>T p.A793S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs777661670, COSV52054873; called by muse, mutect2, varscan2
- DENND5B | c.1592G>T p.W531L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60905134; called by muse, mutect2, varscan2
- DENND6A | c.767A>T p.D256V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV60769400; called by muse, mutect2, varscan2
- DES | c.1103C>A p.A368E | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.657); catalogued as COSV64660692; called by muse, mutect2, varscan2
- DGKG | c.180G>C p.R60S | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV53968435; called by muse, mutect2, varscan2
- DGKK | c.3790C>A p.L1264I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV65708592; called by muse, mutect2, varscan2
- DGKK | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV101052876; called by muse, mutect2, varscan2
- DHTKD1 | c.877G>T p.V293F | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV53804008, COSV53804976; called by muse, mutect2, varscan2
- DIDO1 | c.5587G>T p.V1863L | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV56628350; called by muse, mutect2, varscan2
- DISP3 | c.1806G>T p.W602C | Missense Mutation (SNP) | VAF 80/165 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53832330; called by muse, mutect2, varscan2
- DKC1 | c.1137G>T p.K379N | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV101059859; called by muse, mutect2, varscan2
- DLEC1 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as COSV57302790; called by muse, mutect2, varscan2
- DLG3 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.423); catalogued as COSV52084936; called by muse, mutect2, varscan2
- DMAC1 | c.144G>T p.W48C | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64065912; called by muse, mutect2, varscan2
- DMBT1 | c.5065G>T p.G1689* (on ENST00000338354 / NM_001377530.1; = p.G932* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 46/331 reads (14%) | catalogued as COSV57549922, COSV57551783; called by muse, mutect2, varscan2
- DMXL1 | c.868A>G p.I290V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1480770365, COSV60716577; called by muse, mutect2, varscan2
- DMXL2 | c.434A>T p.E145V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV51850570; called by muse, mutect2, varscan2
- DNAH10 | c.9507G>A p.M3169I (on ENST00000409039; = p.M3108I on NM_207437.3) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1277851155, COSV68997143; called by muse, mutect2, varscan2
- DNAH11 | c.8821G>T p.D2941Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV60966593; called by muse, varscan2
- DNAH2 | c.6454A>T p.T2152S | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV66722474; called by muse, mutect2, varscan2
- DNAH5 | c.6777G>T p.M2259I | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54238912; called by muse, mutect2, varscan2
- DNAI4 | c.2219C>G p.S740C | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV64030346; called by muse, mutect2, varscan2
- DOCK11 | c.4493G>T p.R1498M | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52243515; called by muse, mutect2
- DOCK2 | c.1129C>A p.Q377K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as COSV56972031; called by muse, mutect2, varscan2
- DOCK2 | c.4058C>A p.P1353H | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56972043; called by muse, mutect2, varscan2
- DOP1A | c.5416-1G>C p.X1806_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV52713588; called by muse, mutect2, varscan2
- DOP1B | c.1775G>T p.G592V | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV67694397; called by muse, mutect2, varscan2
- DPP9 | c.776G>A p.C259Y (on ENST00000598800; = p.C288Y on NM_139159.5) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.482); catalogued as COSV53592755; called by muse, mutect2, varscan2
- DPY19L4 | c.1381G>C p.G461R | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV68963362; called by muse, mutect2, varscan2
- DPYS | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs1177067449, COSV60911099; called by muse, mutect2, varscan2
- DPYSL4 | c.786C>G p.D262E | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV100633985, COSV58308614; called by muse, mutect2, varscan2
- DTNA | c.215C>G p.P72R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.744); catalogued as COSV52013958; called by muse, mutect2, varscan2
- DYNC1H1 | c.7037A>T p.Q2346L | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV64139358; called by muse, mutect2, varscan2
- DZANK1 | c.207A>G p.I69M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as COSV52753903; called by muse, mutect2
- EBF1 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs1281257866, COSV100565852, COSV58186604; called by muse, mutect2, varscan2
- EDNRB | c.1163G>T p.C388F (on ENST00000377211 / NM_001201397.1; = p.C298F on NM_000115.5) | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as COSV57525591; called by muse, mutect2, varscan2
- EFCAB3 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV59503369; called by muse, mutect2, varscan2
- EFHB | c.927C>A p.Y309* | Nonsense Mutation (SNP) | VAF 32/95 reads (34%) | catalogued as COSV55545406, COSV55550561; called by muse, mutect2, varscan2
- EGFLAM | c.2336T>A p.V779E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV59309819; called by muse, mutect2, varscan2
- EHMT1 | c.3006G>T p.R1002S | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV71778103, COSV71778611; called by muse, mutect2, varscan2
- EID3 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV61600182; called by muse, mutect2, varscan2
- EIF2AK1 | c.6G>T p.Q2H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.174); catalogued as COSV52240192, COSV99551489; called by muse, mutect2
- ELAVL4 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63917645; called by muse, mutect2, varscan2
- ELK4 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758673354, COSV56985098; called by muse, mutect2, varscan2
- ELMO1 | c.1171C>A p.H391N | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.349); catalogued as COSV60313577; called by muse, mutect2, varscan2
- ELMO2 | c.1252T>C p.C418R | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1314053062, COSV51684433; called by muse, mutect2, varscan2
- ELP1 | c.3605G>T p.R1202L | Missense Mutation (SNP) | VAF 87/253 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV65897505, COSV65898731; called by muse, mutect2, varscan2
- ENGASE | c.2062G>T p.G688W | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56136548; called by muse, mutect2, varscan2
- ENOX2 | c.1758G>T p.Q586H (on ENST00000338144 / NM_001382520.1; = p.Q557H on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57655102; called by muse, mutect2, varscan2
- ENPEP | c.1514A>C p.Y505S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54453906; called by muse, mutect2, varscan2
- EPHA4 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV56038487; called by muse, mutect2, varscan2
- EPHA5 | c.571C>A p.R191S | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56628850, COSV56646986, COSV56676762; called by muse, mutect2, varscan2
- EPHB6 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV67419815; called by muse, mutect2, varscan2
- EPRS1 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65100262; called by muse, mutect2, varscan2
- EPS8 | c.598A>T p.R200W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55533653; called by muse, mutect2, varscan2
- ERGIC3 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV54139378; called by muse, mutect2, varscan2
- ERICH3 | c.3799G>T p.V1267L | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100443380, COSV58616922; called by muse, mutect2, varscan2
- ERVFRD-1 | c.618G>T p.W206C | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV65369566; called by muse, mutect2, varscan2
- ETNPPL | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as COSV56596609; called by muse, mutect2, varscan2
- EVX1 | c.1085C>A p.P362H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1040014588, COSV56085704; called by muse, mutect2, varscan2
- EXD3 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV59809735; called by muse, mutect2, varscan2
- EXOC3L4 | c.663G>T p.E221D | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66295757; called by muse, varscan2
- EXTL3 | c.416A>T p.E139V | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV55039028; called by muse, mutect2, varscan2
- EXTL3 | c.1771C>A p.R591S | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55038507, COSV55039035; called by muse, mutect2, varscan2
- EYS | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs376209811; called by muse, mutect2, varscan2
- EZHIP | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV57956866; called by muse, mutect2, varscan2
- F13A1 | c.1387A>T p.K463* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as COSV53562484; called by muse, mutect2, varscan2
- F8 | c.4468A>T p.T1490S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV64276062; called by muse, mutect2, varscan2
- F8 | c.4331A>G p.D1444G | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as CD930958, COSV64276070; called by muse, mutect2, varscan2
- F8 | c.3371C>A p.S1124* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as CM061752, CX055785, COSV64276078; called by muse, mutect2
- FAAP24 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV54288942; called by muse, mutect2, varscan2
- FABP9 | c.63G>T p.M21I | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV66911666, COSV66911684; called by muse, mutect2
- FAHD2B | c.785G>T p.W262L | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); catalogued as COSV55631606; called by muse, mutect2, varscan2
- FAM135B | c.3061A>T p.T1021S | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV52739124; called by muse, mutect2, varscan2
- FAM135B | c.227A>T p.Y76F | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50531642; called by muse, mutect2, varscan2
- FAM155B | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773653785, COSV52936102, COSV52936961; called by muse, mutect2, varscan2
- FAM171B | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV59005851, COSV59010791; called by muse, mutect2, varscan2
- FAM47B | c.1789C>A p.L597I | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV61455491, COSV61456227; called by muse, mutect2, varscan2
- FAM71F1 | c.888C>A p.C296* | Nonsense Mutation (SNP) | VAF 89/197 reads (45%) | catalogued as COSV59374301; called by muse, mutect2, varscan2
- FAM90A1 | c.1273G>C p.A425P | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs376033532, COSV56713381; called by muse, mutect2, varscan2
- FAT2 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 530/824 reads (64%) | SIFT tolerated (0.7); PolyPhen benign (0.352); catalogued as COSV55824518; called by muse, mutect2, varscan2
- FAT3 | c.1791C>G p.I597M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53113854, COSV53142364; called by muse, mutect2
- FAT3 | c.6790C>A p.L2264I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV53142415; called by muse, mutect2
- FAT3 | c.10498C>G p.H3500D | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV53142437; called by muse, mutect2, varscan2
- FAT4 | c.5038C>A p.L1680I | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV67893260; called by muse, mutect2, varscan2
- FBN2 | c.3373C>T p.L1125F | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as CM148690, COSV52528389; called by muse, mutect2, varscan2
- FBXL7 | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV61649109; called by muse, mutect2, varscan2
- FBXO24 | c.668G>A p.C223Y (on ENST00000241071 / NM_033506.3; = p.C261Y on NM_012172.5) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs1159705438, COSV53827797; called by muse, mutect2, varscan2
- FBXO34 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs201652951, COSV58255625; called by muse, mutect2, varscan2
- FCHSD1 | c.387C>A p.N129K | Missense Mutation (SNP) | VAF 80/153 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs770084242, COSV53352401, COSV53355505; called by muse, mutect2, varscan2
- FCN1 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV65662667, COSV65662828; called by muse, mutect2, varscan2
- FCRL1 | c.786C>A p.F262L | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV63826299; called by muse, mutect2, varscan2
- FCRL5 | c.673del p.R225Gfs*13 | Frame Shift Del (DEL) | VAF 40/197 reads (20%) | catalogued as COSV62515677; called by mutect2, pindel, varscan2
- FDX2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as rs371059833; called by muse, mutect2, varscan2
- FER1L6 | c.4951G>T p.G1651C | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67551457; called by muse, mutect2, varscan2
- FERD3L | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV51763452; called by muse, mutect2, varscan2
- FEV | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55386998; called by muse, mutect2, varscan2
- FGF14 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV65949591; called by muse, mutect2
- FGFR2 | c.2409G>T p.M803I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV60652920; called by muse, mutect2, varscan2
- FLG | c.6460C>T p.Q2154* | Nonsense Mutation (SNP) | VAF 179/738 reads (24%) | catalogued as rs1287937927, COSV100911464, COSV64244744; called by muse, varscan2
- FLG | c.6415C>A p.R2139S | Missense Mutation (SNP) | VAF 153/702 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV64243402, COSV64244746; called by muse, varscan2
- FLG | c.4106G>T p.R1369I | Missense Mutation (SNP) | VAF 393/1104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV64244749; called by muse, mutect2, varscan2
- FLNA | c.7360A>T p.T2454S (on ENST00000369850 / NM_001110556.2; = p.T2446S on NM_001456.3) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV61047370; called by muse, mutect2, varscan2
- FLNC | c.3490G>T p.G1164C | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57959957; called by muse, mutect2, varscan2
- FLT3 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV54061266; called by muse, mutect2, varscan2
- FMO1 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 37/174 reads (21%) | catalogued as COSV61446744; called by muse, mutect2, varscan2
- FMR1 | c.1030A>G p.R344G | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.374); catalogued as rs1557179867, COSV54425674; called by muse, mutect2, varscan2
- FNDC1 | c.2516G>A p.R839Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV51940197, COSV51942921, COSV99794521; called by muse, mutect2, varscan2
- FOLR2 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53351997; called by muse, mutect2, varscan2
- FOXD4L1 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99380205; called by muse, mutect2, varscan2
- FOXF2 | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV99452938; called by muse, mutect2, varscan2
- FOXL1 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV57214766; called by muse, mutect2, varscan2
- FOXN4 | c.1466C>A p.S489Y | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV54495474, COSV54496030; called by muse, mutect2, varscan2
- FOXRED1 | c.529G>T p.V177L | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV55007763; called by muse, mutect2, varscan2
- FRMD3 | c.959C>G p.S320* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV58465154; called by muse, mutect2, varscan2
- FRMD7 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs756646876, COSV53747574; called by muse, mutect2, varscan2
- FRS2 | c.515G>C p.S172T | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV54727883; called by muse, mutect2, varscan2
- FUT6 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV54607063; called by muse, mutect2, varscan2
- GABPA | c.1168G>T p.V390F | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61396977; called by muse, mutect2, varscan2
- GABRA2 | c.588T>A p.Y196* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as COSV62916888; called by muse, mutect2, varscan2
- GABRA5 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV59482478; called by muse, mutect2, varscan2
- GALNT14 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs146467165; called by muse, mutect2, varscan2
- GALNT15 | c.421G>T p.G141W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV100327277; called by muse, mutect2, varscan2
- GALNT2 | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100795874, COSV64196252; called by muse, mutect2
- GANAB | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV60466694; called by muse, mutect2, varscan2
- GAS1 | c.608G>T p.C203F | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV53927531, COSV53927562; called by muse, mutect2, varscan2
- GAS2 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99534670; called by muse, mutect2, varscan2
- GATAD2A | c.1811A>C p.H604P | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53072847; called by muse, mutect2, varscan2
- GCDH | c.850G>T p.G284W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.45); catalogued as COSV99535706; called by muse, mutect2
- GCDH | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs749033627, COSV53365606; called by muse, mutect2
- GCLC | c.1296G>T p.E432D (on ENST00000643939; = p.E430D on NM_001498.4) | Missense Mutation (SNP) | VAF 82/203 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as COSV57596569; called by muse, mutect2, varscan2
- GCN1 | c.7659C>A p.S2553R | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.25); catalogued as COSV56111070; called by muse, mutect2
- GDF9 | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV51526812; called by muse, mutect2, varscan2
- GFRAL | c.58del p.Q20Kfs*8 | Frame Shift Del (DEL) | VAF 32/105 reads (30%) | catalogued as COSV61236579; called by mutect2, pindel, varscan2
- GFRAL | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 94/265 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61233109; called by muse, mutect2, varscan2
- GHR | c.773C>A p.T258K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0.026); catalogued as COSV50120264; called by muse, mutect2, varscan2
- GINS4 | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs201557458, COSV52531862; called by muse, mutect2, varscan2
- GJB4 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as COSV58356631; called by muse, mutect2, varscan2
- GJD2 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.511); catalogued as rs1334045483, COSV51749306; called by muse, mutect2, varscan2
- GLI2 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.042); catalogued as rs990168694, COSV100082306; called by muse, mutect2, varscan2
- GLRB | c.92_93insT p.K31Nfs*27 | Frame Shift Ins (INS) | VAF 9/59 reads (15%) | catalogued as COSV100029461; called by mutect2, pindel, varscan2
- GLUD2 | c.1294G>C p.A432P | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV60152514; called by muse, mutect2, varscan2
- GNB3 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs782154852, COSV51834919; called by muse, mutect2, varscan2
- GNB5 | c.397G>T p.D133Y (on ENST00000261837 / NM_016194.4; = p.D91Y on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55900213; called by muse, mutect2, varscan2
- GNPAT | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs199745265, COSV64153833; called by muse, mutect2, varscan2
- GOLGA6A | c.2023C>T p.H675Y | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.404); catalogued as COSV99296986; called by muse, mutect2, varscan2
- GPALPP1 | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62706218; called by muse, mutect2, varscan2
- GPC4 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63698718; called by muse, mutect2
- GPC5 | c.1118C>A p.T373K | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV65612207; called by muse, mutect2, varscan2
- GPI | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 38/574 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62893708, COSV62894438; called by muse, mutect2
- GPLD1 | c.760A>G p.M254V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV57758171; called by muse, mutect2, varscan2
- GPR12 | c.646C>A p.L216I | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV67344608; called by muse, mutect2, varscan2
- GPR132 | c.470G>A p.R157K | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs762905666, COSV61678173; called by muse, mutect2, varscan2
- GPR137C | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.808); catalogued as COSV58705969; called by muse, mutect2, varscan2
- GPR27 | c.837G>T p.E279D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV55205761; called by muse, mutect2, varscan2
- GPRASP1 | c.2167T>A p.W723R | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV64356073; called by muse, mutect2, varscan2
- GPRASP2 | c.1246G>T p.G416W | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59991987; called by muse, mutect2
- GREB1 | c.2050C>T p.Q684* | Nonsense Mutation (SNP) | VAF 127/275 reads (46%) | catalogued as COSV52191678; called by muse, mutect2, varscan2
- GRID1 | c.253C>A p.Q85K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.285); catalogued as COSV60040086; called by muse, mutect2, varscan2
- GRID2 | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.237); catalogued as COSV56231498; called by muse, mutect2, varscan2
- GRIK3 | c.2543G>T p.R848L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV66135600, COSV66143041; called by muse, mutect2, varscan2
- GRIN3B | c.1748del p.A583Gfs*64 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as COSV52260688, COSV99312564; called by mutect2, pindel*, varscan2
- GRK1 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1000323290, COSV59553561; called by muse, mutect2, varscan2
- GRXCR2 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV100939969; called by muse, mutect2
- GRXCR2 | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100939970; called by muse, mutect2
- GSR | c.1477G>C p.V493L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55321845; called by muse, mutect2, varscan2
- GUCY1A2 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56493619, COSV99975077; called by mutect2, varscan2
- GUCY2C | c.2569G>C p.D857H | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53792672; called by muse, mutect2, varscan2
- GUCY2F | c.1791G>T p.M597I | Missense Mutation (SNP) | VAF 109/302 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV54305487; called by muse, mutect2, varscan2
- GYPC | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52147498; called by muse, mutect2, varscan2
- GZMB | c.486G>T p.E162D | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as COSV53540820, COSV53542479; called by muse, mutect2, varscan2
- H2BW1 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as COSV54220826; called by muse, mutect2, varscan2
- H3C8 | c.214G>T p.V72L | Missense Mutation (SNP) | VAF 74/139 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV100009991; called by muse, mutect2, varscan2
- H4C7 | c.259G>T p.V87L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV55100414, COSV55100792; called by muse, mutect2, varscan2
- H4C9 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV62890062; called by muse, mutect2, varscan2
- HAPLN1 | c.614G>T p.C205F | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57149980; called by muse, mutect2, varscan2
- HCN1 | c.645G>T p.M215I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs1439791679, COSV57512177, COSV57523512; called by muse, mutect2
- HDAC9 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV67779003; called by muse, mutect2
- HDAC9 | c.2204G>T p.G735V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67779010; called by muse, mutect2
- HDAC9 | c.3136G>T p.D1046Y (on ENST00000441542 / NM_178425.3; = p.D1043Y on NM_178423.3) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV67773067, COSV67779020; called by muse, mutect2, varscan2
- HDAC9 | c.3193G>T p.E1065* (on ENST00000441542 / NM_178425.3; = p.E1062* on NM_178423.3) | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV67779027; called by muse, mutect2, varscan2
- HDDC2 | c.391C>A p.Q131K | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.246); catalogued as COSV59532659; called by muse, mutect2, varscan2
- HEATR1 | c.5107G>C p.E1703Q | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as COSV63982110; called by muse, mutect2
- HECW1 | c.2975G>T p.R992L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV67823382, COSV67833195; called by muse, varscan2
- HECW2 | c.1214G>T p.R405M | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.635); catalogued as COSV53656233, COSV53666352; called by muse, mutect2, varscan2
- HEPACAM | c.567T>A p.N189K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV53431148; called by muse, mutect2, varscan2
- HEPACAM | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53431159, COSV53431333; called by muse, mutect2, varscan2
- HEPHL1 | c.2183G>T p.R728L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV59894044; called by muse, mutect2, varscan2
- HERC2 | c.1577G>T p.R526L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV55336082; called by muse, mutect2, varscan2
- HGF | c.228G>T p.R76S | Missense Mutation (SNP) | VAF 85/166 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV55953120; called by muse, mutect2, varscan2
- HHAT | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as rs977412599, COSV54803897; called by muse, mutect2, varscan2
- HIF3A | c.1169C>G p.A390G (on ENST00000377670 / NM_152795.4; = p.A321G on NM_022462.4) | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV52201577, COSV52204649; called by muse, mutect2, varscan2
- HK2 | c.2251G>T p.G751C | Missense Mutation (SNP) | VAF 139/254 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51877173; called by muse, mutect2, varscan2
- HLF | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 150/211 reads (71%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as COSV56830827; called by muse, mutect2, varscan2
- HMCN1 | c.11741C>G p.A3914G | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV54918224; called by muse, mutect2, varscan2
- HNF4G | c.641G>T p.R214L (on ENST00000354370 / NM_001330561.2; = p.R261L on NM_004133.5) | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV62968669; called by muse, mutect2, varscan2
- HNRNPA3 | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV66821018; called by muse, mutect2, varscan2
- HNRNPR | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV56422930; called by muse, mutect2, varscan2
- HOXA3 | c.537C>A p.C179* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100415456, COSV57827769; called by muse, mutect2, varscan2
- HOXC12 | c.260G>C p.R87P | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV54535412; called by muse, mutect2
- HRNR | c.5579G>C p.R1860P | Missense Mutation (SNP) | VAF 170/1397 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs766970218, COSV100912906, COSV64254362; called by muse, varscan2
- HSD3B2 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65593639; called by muse, mutect2, varscan2
- HSF2BP | c.693G>T p.V231= | Splice Region (SNP) | VAF 20/44 reads (45%) | catalogued as COSV52357979; called by muse, mutect2, varscan2
- HSP90AB1 | c.306G>T p.L102F | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV62335557; called by muse, mutect2
- HSP90B1 | c.762A>T p.E254D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.553); catalogued as COSV55356629; called by muse, mutect2, varscan2
- HTR1F | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV60390303; called by muse, mutect2, varscan2
- HTR2C | c.163T>G p.W55G | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52201219, COSV52218410; called by muse, mutect2, varscan2
- IER2 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV52848479; called by muse, mutect2, varscan2
- IFNA1 | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV52806812; called by muse, mutect2, varscan2
- IFT172 | c.1911G>T p.E637D | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV53136256; called by muse, mutect2, varscan2
- IGF2BP2 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as COSV60488607; called by muse, mutect2, varscan2
- IGHMBP2 | c.2640G>T p.E880D | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV54824158; called by muse, varscan2
- IGHMBP2 | c.2716G>T p.V906F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV54824169; called by muse, varscan2
- IGHV3-72 | c.205C>A p.R69S | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as COSV70409700; called by muse, mutect2, varscan2
- IGHV4-34 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs587753421; called by muse, varscan2
- IGHV4-34 | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as rs780409920; called by muse, varscan2
- IGSF10 | c.1213A>G p.K405E | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs746753465, COSV56788390; called by muse, mutect2, varscan2
- IGSF21 | c.132G>T p.L44F | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52138452; called by muse, mutect2, varscan2
- IGSF22 | c.1781C>A p.A594D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60036365; called by muse, mutect2, varscan2
- IL15 | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.95); catalogued as COSV56726765; called by mutect2, varscan2
- IL16 | c.172C>A p.H58N | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.591); catalogued as COSV57266012; called by muse, mutect2, varscan2
- IL1RAP | c.917G>C p.R306T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV50765790; called by mutect2, varscan2
- IMPG2 | c.3176A>G p.D1059G | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV51982006; called by muse, mutect2, varscan2
- INHBA | c.849G>T p.E283D | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV54223158; called by muse, mutect2, varscan2
- INHBA | c.417G>C p.E139D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV54222705, COSV54223169; called by muse, mutect2
- INPP4B | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV53734762; called by muse, mutect2, varscan2
- INPP4B | c.377G>C p.R126P | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.585); catalogued as COSV53720176, COSV53734790; called by muse, mutect2
- INPP5B | c.2671G>T p.E891* (on ENST00000373023; = p.E811* on NM_005540.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | catalogued as COSV65961702; called by muse, mutect2, varscan2
- INSIG2 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV55523113; called by muse, mutect2
- INSRR | c.1807G>T p.A603S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.041); catalogued as COSV63875404; called by muse, mutect2, varscan2
- IQCF2 | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs766644693, COSV60761667; called by muse, varscan2
- IRAK3 | c.191A>T p.Q64L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54163561; called by muse, mutect2, varscan2
- IRS1 | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 93/155 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59338055; called by muse, mutect2, varscan2
- IRS4 | c.2088G>T p.E696D | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV100929513, COSV64533891, COSV64534910; called by muse, mutect2, varscan2
- ISL1 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57934633; called by muse, mutect2, varscan2
- ITCH | c.1745C>T p.P582L (on ENST00000262650 / NM_001257137.3; = p.P541L on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV52934308; called by muse, varscan2
- ITGA7 | c.1631C>T p.S544L (on ENST00000555728; = p.S500L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs753481574, COSV57697799; called by muse, mutect2, varscan2
- ITGAX | c.71C>A p.T24K | Missense Mutation (SNP) | VAF 81/248 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV51648301; called by muse, mutect2, varscan2
- ITGB1BP2 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV52138373; called by muse, mutect2, varscan2
- ITLN2 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63537993; called by muse, mutect2, varscan2
- ITPRID1 | c.254C>A p.T85N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV60078296; called by muse, mutect2, varscan2
- JPH2 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 31/106 reads (29%) | catalogued as COSV65904571, COSV65904658; called by muse, mutect2, varscan2
- JRK | c.191G>C p.R64P | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as COSV101401113, COSV70630101; called by muse, mutect2, varscan2
- JSRP1 | c.718C>G p.R240G | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV55555760; called by muse, mutect2, varscan2
- KALRN | c.8681G>T p.R2894M (on ENST00000360013 / NM_001024660.4; = p.R1197M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52259727, COSV52260509; called by muse, mutect2, varscan2
- KBTBD4 | c.18G>T p.E6D | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs756893187, COSV55455447; called by muse, mutect2, varscan2
- KCNB2 | c.1219C>A p.L407M | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73051477; called by muse, mutect2, varscan2
- KCNC2 | c.1336C>A p.Q446K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs200669582, COSV100128190; called by muse, mutect2, varscan2
- KCNC2 | c.432C>G p.D144E | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV54373557; called by muse, mutect2, varscan2
- KCNC4 | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV63926102; called by muse, mutect2
- KCNH2 | c.1524C>A p.F508L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV51132408, COSV51209028; called by muse, mutect2, varscan2
- KCNH8 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as COSV60466833, COSV60469851; called by muse, mutect2, varscan2
- KCNH8 | c.2583G>T p.E861D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs771461404, COSV100108407; called by muse, mutect2, varscan2
- KCNH8 | c.2584G>T p.E862* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100108413; called by muse, mutect2, varscan2
- KCNJ5 | c.1116G>C p.R372S | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs756845312, COSV57968341; called by muse, mutect2, varscan2
- KCNK13 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as COSV56414959; called by muse, mutect2
- KCNK9 | c.1089C>A p.D363E | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772870980, COSV57285077; called by muse, mutect2, varscan2
- KCNK9 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100270323; called by muse, mutect2, varscan2
- KCNK9 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100270330; called by muse, mutect2, varscan2
- KDM5B | c.4249G>T p.E1417* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV52510094; called by muse, mutect2, varscan2
- KDR | c.3332T>C p.I1111T | Missense Mutation (SNP) | VAF 93/237 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55770447; called by muse, mutect2, varscan2
- KEL | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV100786861, COSV100786913; called by muse, mutect2
- KEL | c.2004C>A p.S668R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs757027102, COSV100786862; called by muse, mutect2, varscan2
- KIAA0895L | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 11/18 reads (61%) | catalogued as COSV51783655; called by muse, mutect2, varscan2
- KIAA1109 | c.14302G>T p.E4768* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV52682663; called by muse, mutect2, varscan2
- KIAA1210 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as rs369057021, COSV68175642; called by muse, mutect2, varscan2
- KIAA1549L | c.182C>T p.P61L (on ENST00000321505; = p.P358L on NM_012194.3) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs751498078, COSV55777334; called by muse, mutect2, varscan2
- KIAA1586 | c.1522C>A p.H508N | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV66057037; called by muse, mutect2
- KIDINS220 | c.4963G>A p.E1655K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as rs970613821, COSV56750940; called by muse, mutect2, varscan2
- KIF1B | c.2454G>T p.R818S (on ENST00000377086 / NM_001365952.1; = p.R772S on NM_015074.3) | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.468); catalogued as COSV55811932; called by muse, mutect2, varscan2
- KIF21B | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59761786; called by muse, mutect2, varscan2
- KIF26A | c.866C>A p.T289N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV59468317; called by muse, mutect2, varscan2
- KIF3B | c.1968G>T p.R656S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV65228435; called by muse, mutect2, varscan2
- KIFC2 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); catalogued as rs566652240, COSV56762055; called by muse, mutect2, varscan2
- KIRREL1 | c.1044+1G>C p.X348_splice | Splice Site (SNP) | VAF 22/110 reads (20%) | catalogued as COSV63289262; called by muse, mutect2, varscan2
- KIRREL1 | c.2006G>T p.G669V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as rs1210602170, COSV63289276; called by muse, mutect2, varscan2
- KLB | c.1390G>T p.D464Y | Missense Mutation (SNP) | VAF 126/230 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57301902, COSV57303089; called by muse, mutect2, varscan2
- KLC2 | c.1204G>T p.G402C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57583521; called by muse, varscan2
- KLF3 | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 412/509 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV54711627, COSV99789633; called by muse, mutect2, varscan2
- KLHL1 | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64776425; called by muse, mutect2
- KLHL11 | c.877A>T p.R293W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59862524; called by muse, mutect2, varscan2
- KLHL28 | c.871A>T p.K291* | Nonsense Mutation (SNP) | VAF 16/140 reads (11%) | catalogued as COSV61888770; called by muse, mutect2, varscan2
- KMT2B | c.2335G>T p.G779C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52891494; called by muse, mutect2, varscan2
- KMT2D | c.2326G>T p.E776* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV56463115; called by muse, mutect2, varscan2
- KRT19 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV54180650; called by muse, mutect2, varscan2
- KRTAP10-6 | c.962C>G p.P321R | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV59970457; called by muse, mutect2, varscan2
- KRTAP13-4 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.124); catalogued as rs774044352, COSV61879785; called by muse, mutect2, varscan2
- KRTAP24-1 | c.50C>G p.T17S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV61089465, COSV61089808; called by muse, mutect2, varscan2
- KRTAP5-10 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV64795339; called by muse, mutect2, varscan2
- KRTAP9-8 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV54200478; called by muse, mutect2, varscan2
- KSR1 | c.614G>T p.S205I (on ENST00000644974 / NM_001367810.1; = p.S68I on NM_014238.2) | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as COSV52035777; called by muse, mutect2, varscan2
- KTN1 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV68022390, COSV68024467; called by muse, mutect2, varscan2
- LAMB1 | c.1315G>T p.V439F | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV55967329; called by muse, mutect2, varscan2
- LAMB4 | c.3332G>T p.S1111I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.5); catalogued as COSV52724430; called by muse, mutect2, varscan2
- LAMC1 | c.3586G>A p.D1196N | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV51154527; called by muse, mutect2, varscan2
- LAPTM5 | c.441C>A p.S147R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53853910; called by muse, mutect2
- LAS1L | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs113345668, COSV56708190; called by muse, mutect2, varscan2
- LATS1 | c.2272G>T p.A758S | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV99485228; called by muse, mutect2, varscan2
- LAYN | c.537G>T p.K179N (on ENST00000375615 / NM_001258390.1; = p.K171N on NM_178834.5) | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65105162; called by muse, mutect2, varscan2
- LCE1E | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.154); catalogued as rs905545241, COSV64219953; called by muse, mutect2, varscan2
- LCE4A | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 107/418 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as COSV59266998; called by muse, mutect2, varscan2
- LCP1 | c.984G>T p.K328N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.41); catalogued as COSV100549668; called by muse, mutect2, varscan2
- LCP2 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 86/197 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV50456495, COSV50462054; called by muse, mutect2, varscan2
- LDLRAD3 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59683087, COSV59684916; called by muse, mutect2, varscan2
- LEMD2 | c.688T>G p.W230G | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as rs965203969, COSV53394578; called by muse, mutect2, varscan2
- LILRB1 | c.1388G>C p.S463T (on ENST00000427581; = p.S427T on NM_006669.6) | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.513); catalogued as COSV61120029; called by muse, mutect2, varscan2
- LIMS2 | c.569A>T p.H190L (on ENST00000355119 / NM_001161403.3; = p.H214L on NM_017980.4) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV55756243; called by muse, mutect2, varscan2
- LIPN | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68384248; called by muse, mutect2, varscan2
- LMNTD1 | c.81G>C p.L27F | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV51445960, COSV51448789; called by muse, mutect2, varscan2
- LMO7 | c.4919C>T p.S1640L (on ENST00000357063; = p.S1321L on NM_005358.5) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV58537640; called by muse, mutect2, varscan2
- LONRF2 | c.874C>T p.L292F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs779900474, COSV66541448; called by muse, mutect2, varscan2
- LPA | c.2459G>T p.R820M | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.063); catalogued as COSV100306068, COSV100308086; called by muse, mutect2, varscan2
- LRFN1 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.176); catalogued as COSV50460154, COSV50474382; called by muse, mutect2, varscan2
- LRFN2 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57830911; called by muse, mutect2
- LRGUK | c.982A>C p.I328L | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53640559, COSV53641656; called by muse, mutect2, varscan2
- LRP1B | c.10295-1G>T p.X3432_splice | Splice Site (SNP) | VAF 31/50 reads (62%) | catalogued as COSV67248326, COSV67281791; called by muse, mutect2, varscan2
- LRRC26 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.035); catalogued as COSV59298533; called by muse, mutect2, varscan2
- LRRC32 | c.226C>A p.R76S | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV52631435, COSV52634094; called by muse, mutect2, varscan2
- LRRC43 | c.1463G>T p.G488V | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60291340; called by muse, mutect2, varscan2
- LRRC4C | c.1055A>C p.Y352S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV53431768; called by muse, mutect2
- LRRC4C | c.918C>G p.N306K | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV53431780; called by muse, mutect2, varscan2
- LRRK1 | c.1359G>T p.K453N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV52619342; called by muse, mutect2, varscan2
- LSAMP | c.962C>A p.A321D | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.45); PolyPhen benign (0.326); catalogued as COSV61286188, COSV61301500; called by muse, mutect2, varscan2
- LSS | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs767359110, COSV62701795; called by muse, mutect2, varscan2
- LTK | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV55492153; called by muse, mutect2
- LUZP4 | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV100904832; called by muse, mutect2, varscan2
- LY96 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | catalogued as COSV99514278; called by muse, mutect2, varscan2
- LYZL2 | c.389G>T p.R130I (on ENST00000375318; = p.R84I on NM_183058.3) | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV64684660; called by muse, mutect2, varscan2
- MACIR | c.140C>A p.T47N | Missense Mutation (SNP) | VAF 105/129 reads (81%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV60635441; called by muse, mutect2, varscan2
- MAGEB3 | c.95C>A p.A32E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as COSV64397363, COSV64397434; called by muse, mutect2, varscan2
- MAGI2 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1287178660, COSV62679572; called by muse, mutect2, varscan2
- MAGI2 | c.64A>T p.R22W | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.969); catalogued as COSV62679579; called by muse, mutect2
- MAL2 | c.153G>T p.W51C | Missense Mutation (SNP) | VAF 147/419 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52662020; called by muse, mutect2, varscan2
- MAP1A | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55810736; called by muse, mutect2, varscan2
- MAP2 | c.4138G>T p.D1380Y | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52281188, COSV52299005; called by muse, mutect2, varscan2
- MAP2 | c.4753G>A p.A1585T | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0.015); catalogued as COSV52299024; called by muse, mutect2, varscan2
- MAP4K4 | c.2932G>A p.V978I (on ENST00000347699 / NM_001242559.2; = p.V896I on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.93); catalogued as COSV56335855; called by muse, mutect2, varscan2
- MAP7D1 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60217374; called by muse, mutect2, varscan2
- MAPRE1 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV65033205; called by muse, mutect2, varscan2
- MARK2 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV59285915; called by muse, mutect2, varscan2
- MAST1 | c.604C>A p.R202S | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.67); PolyPhen benign (0.031); catalogued as COSV52250543; called by muse, mutect2, varscan2
- MCF2 | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58489729, COSV58492311; called by muse, mutect2
- MCF2 | c.1444C>A p.P482T | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV58489813; called by muse, mutect2, varscan2
- MCF2 | c.1316C>A p.P439H | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58489844, COSV58491464; called by muse, mutect2, varscan2
- MCM9 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57648271, COSV99995721; called by muse, mutect2, varscan2
- MCM9 | c.1015G>C p.G339R | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57647725, COSV57647965, COSV99995724; called by muse, mutect2, varscan2
- MCMDC2 | c.1216G>C p.G406R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV58037983; called by muse, mutect2, varscan2
- MDGA2 | c.2984C>A p.T995N (on ENST00000399232 / NM_001113498.2; = p.T697N on NM_182830.4) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.005); catalogued as COSV62103217; called by muse, mutect2, varscan2
- MED12 | c.6188A>G p.Q2063R | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.067); catalogued as COSV61347411; called by muse, varscan2
- MED17 | c.332T>G p.V111G | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as COSV52602000; called by muse, mutect2, varscan2
- MEGF10 | c.312G>T p.M104I | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV57252947; called by muse, mutect2, varscan2
- MFAP1 | c.78A>T p.K26N | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV51039939; called by muse, mutect2, varscan2
- MFN1 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99764173; called by muse, mutect2, varscan2
- MFSD1 | c.636del p.I213Sfs*4 | Frame Shift Del (DEL) | VAF 31/112 reads (28%) | catalogued as COSV99963621; called by mutect2, pindel, varscan2
- MFSD8 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as rs1356954922, COSV56551887; called by muse, mutect2, varscan2
- MINAR1 | c.1310C>G p.S437C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV59584649; called by muse, mutect2, varscan2
- MMP15 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 58/94 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV54680557; called by muse, mutect2, varscan2
- MMP16 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as rs1201596629, COSV54173119; called by muse, mutect2, varscan2
- MMRN1 | c.3550G>T p.D1184Y | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753756470, COSV53340066; called by muse, mutect2, varscan2
- MON2 | c.643G>C p.D215H | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54810442; called by muse, mutect2, varscan2
- MORC4 | c.2160G>C p.E720D | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.142); catalogued as COSV55244680; called by muse, mutect2
- MPZL1 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV63256871; called by muse, mutect2, varscan2
- MRC1 | c.4120+2T>A p.X1374_splice | Splice Site (SNP) | VAF 22/77 reads (29%) | catalogued as COSV99519262; called by muse, mutect2, varscan2
- MRC2 | c.729G>T p.Q243H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV57641994; called by muse, mutect2, varscan2
- MROH2B | c.3874del p.E1292Nfs*14 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as COSV68183148; called by mutect2, pindel, varscan2
- MROH5 | c.3512T>A p.L1171Q | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61472305; called by muse, mutect2, varscan2
- MRPS28 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs180680255, COSV52563585; called by muse, mutect2, varscan2
- MS4A14 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV55735090, COSV55736401; called by muse, mutect2, varscan2
- MS4A3 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV53935800, COSV99614507; called by muse, mutect2, varscan2
- MS4A3 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53935946, COSV99614511; called by muse, mutect2, varscan2
- MS4A6E | c.134T>A p.V45D | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV55727526; called by muse, mutect2, varscan2
- MSRB2 | c.119-1G>T p.X40_splice | Splice Site (SNP) | VAF 40/77 reads (52%) | catalogued as COSV64737718; called by muse, mutect2, varscan2
- MTNR1A | c.909G>T p.R303S | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100208237, COSV56156921; called by muse, mutect2, varscan2
- MTUS2 | c.1848G>T p.E616D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as COSV101462065; called by muse, mutect2, varscan2
- MUC16 | c.42876G>C p.W14292C | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV66694599; called by muse, mutect2, varscan2
- MUC16 | c.36730G>T p.E12244* | Nonsense Mutation (SNP) | VAF 97/298 reads (33%) | catalogued as rs371709616, COSV101200069, COSV67465014; called by muse, mutect2, varscan2
- MUC16 | c.26191G>T p.G8731* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV67479428; called by muse, mutect2, varscan2
- MUC16 | c.7661C>G p.S2554C | Missense Mutation (SNP) | VAF 57/70 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV67476356, COSV67479433; called by muse, mutect2, varscan2
- MUC17 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 125/332 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs762353876, COSV60295549, COSV60295647; called by muse, mutect2, varscan2
- MUC7 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.439); catalogued as COSV59219378; called by muse, mutect2, varscan2
- MYBPC1 | c.1658C>A p.P553Q (on ENST00000550270 / NM_206820.2; = p.P578Q on NM_002465.4) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62255224; called by muse, mutect2, varscan2
- MYBPC3 | c.1087A>G p.T363A | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV57030677; called by muse, mutect2
- MYCBP2 | c.11060G>T p.G3687V (on ENST00000357337; = p.G3725V on NM_015057.5) | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV62028956; called by muse, mutect2
- MYH1 | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56852654; called by muse, mutect2, varscan2
- MYH14 | c.3391C>T p.R1131W | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373919106, COSV51824636; called by muse, mutect2, varscan2
- MYH6 | c.897G>T p.L299= | Splice Region (SNP) | VAF 140/465 reads (30%) | catalogued as COSV62452610; called by muse, mutect2, varscan2
- MYO15A | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV52760772, COSV52769060; called by muse, mutect2, varscan2
- MYO16 | c.3698A>C p.Q1233P | Missense Mutation (SNP) | VAF 228/273 reads (84%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV62754962; called by muse, mutect2, varscan2
- MYO1A | c.2672G>T p.G891V | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.972); catalogued as COSV100270559; called by muse, mutect2, varscan2
- MYO1A | c.2671G>C p.G891R | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.972); catalogued as COSV100270560; called by muse, mutect2, varscan2
- MYO1F | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 77/119 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV57797585; called by muse, mutect2, varscan2
- MYO3A | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV56339220; called by muse, mutect2, varscan2
- MYO5A | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs761247058, COSV100697920, COSV62562393; called by muse, mutect2, varscan2
- MYO9A | c.2512G>T p.G838* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as COSV61854114; called by muse, mutect2, varscan2
- N4BP3 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 11/17 reads (65%) | catalogued as COSV51064357; called by muse, mutect2, varscan2
- NABP1 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs868255520, COSV57139091; called by muse, mutect2, varscan2
- NALCN | c.4520A>T p.K1507M | Missense Mutation (SNP) | VAF 247/313 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51949708; called by muse, mutect2, varscan2
- NALCN | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 233/334 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51932789, COSV51949724; called by muse, mutect2, varscan2
- NAP1L2 | c.1017G>T p.K339N | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65172756; called by muse, mutect2, varscan2
- NAP1L3 | c.854C>A p.P285H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.029); catalogued as COSV59076632; called by muse, mutect2, varscan2
- NAV3 | c.7139C>A p.S2380Y (on ENST00000397909 / NM_001024383.2; = p.S2358Y on NM_014903.6) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57095652; called by muse, mutect2, varscan2
- NBAS | c.6432+1G>T p.X2144_splice | Splice Site (SNP) | VAF 23/94 reads (24%) | catalogued as COSV55729499; called by muse, mutect2, varscan2
- NCKAP1 | c.965A>G p.N322S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.038); catalogued as COSV62942200; called by muse, mutect2, varscan2
- NCOA2 | c.3263G>C p.R1088P | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV51218889, COSV51220965; called by muse, mutect2, varscan2
- NDN | c.5C>G p.S2* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as COSV59360551; called by muse, mutect2, varscan2
- NEIL2 | c.860A>T p.Q287L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.318); catalogued as COSV52707333; called by muse, mutect2
- NELL2 | c.1917C>A p.D639E | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV61579776; called by muse, mutect2, varscan2
- NEU3 | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs746004555, COSV99579146; called by muse, mutect2, varscan2
- NEUROD6 | c.495A>T p.L165F | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51772473; called by muse, mutect2, varscan2
- NEXMIF | c.4395G>C p.K1465N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV50055246; called by muse, mutect2, varscan2
- NF1 | c.2741G>T p.R914L | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.866); catalogued as COSV62200055, COSV62207925; called by muse, mutect2, varscan2
- NFASC | c.1655A>T p.K552I (on ENST00000339876 / NM_001378329.1; = p.K563I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/242 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV58372188; called by muse, mutect2, varscan2
- NFXL1 | c.1598C>A p.T533K | Missense Mutation (SNP) | VAF 79/320 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV61199780; called by muse, mutect2, varscan2
- NID1 | c.3625C>A p.H1209N | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV51624580; called by muse, mutect2, varscan2
- NID2 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV53499595; called by muse, mutect2, varscan2
- NINL | c.3587A>T p.D1196V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.242); catalogued as COSV54005628; called by muse, mutect2, varscan2
- NLRC5 | c.2243G>T p.S748I | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99346425; called by muse, mutect2, varscan2
- NLRP11 | c.1831C>G p.P611A | Missense Mutation (SNP) | VAF 133/160 reads (83%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV64087068, COSV64088224; called by muse, mutect2, varscan2
- NLRP8 | c.506C>A p.T169N | Missense Mutation (SNP) | VAF 178/205 reads (87%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV52590589; called by muse, mutect2, varscan2
- NOD2 | c.857G>A p.G286D | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV56052993; called by muse, mutect2, varscan2
- NOS1AP | c.1275G>C p.L425F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.77); catalogued as COSV62637460; called by muse, mutect2, varscan2
- NOSIP | c.719G>C p.R240P | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV59199459; called by muse, mutect2, varscan2
- NOTCH1 | c.5327C>G p.S1776C | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV53071482; called by muse, mutect2, varscan2
- NOVA1 | c.1121G>C p.S374T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.1); catalogued as COSV57482084; called by muse, mutect2, varscan2
- NPAP1 | c.2429C>A p.A810D | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.192); catalogued as COSV61508173, COSV61508894; called by muse, mutect2, varscan2
- NPAT | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | catalogued as rs774287167, COSV53719502, COSV99586259; called by muse, mutect2, varscan2
- NPAT | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53719509; called by muse, mutect2, varscan2
- NPBWR2 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | catalogued as COSV63900349; called by muse, mutect2, varscan2
- NPR1 | c.1850G>T p.R617L | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64117855, COSV64118280; called by muse, mutect2, varscan2
- NPTX2 | c.582C>A p.H194Q | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.794); catalogued as COSV55718109; called by muse, mutect2, varscan2
- NPY2R | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as rs1245202215, COSV61527268, COSV61528909; called by muse, mutect2, varscan2
- NR1H4 | c.221C>T p.S74L (on ENST00000551379 / NM_001206993.2; = p.S64L on NM_005123.4) | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as COSV51854223; called by muse, mutect2, varscan2
- NR4A1 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.87); PolyPhen benign (0.006); catalogued as COSV54485035, COSV99671727; called by muse, mutect2, varscan2
- NRAS | c.451-1G>T p.X151_splice | Splice Site (SNP) | VAF 18/53 reads (34%) | catalogued as COSV65732587; called by muse, mutect2, varscan2
- NRSN1 | c.14G>T p.S5I | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV65894267; called by muse, mutect2, varscan2
- NRXN1 | c.3181C>T p.R1061W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765632172, COSV58471239; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN1 | c.2879G>T p.G960V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100453252; called by muse, mutect2, varscan2
- NRXN2 | c.1312C>A p.L438M | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55458094; called by muse, mutect2, varscan2
- NUP205 | c.4901G>T p.S1634I | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.136); catalogued as COSV53662751; called by muse, mutect2, varscan2
- NUP98 | c.4175A>T p.Q1392L (on ENST00000359171 / NM_001365126.1; = p.Q1375L on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/304 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as COSV61435241; called by muse, mutect2, varscan2
- NUTM1 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV100412074; called by muse, mutect2, varscan2
- NXF3 | c.1186G>C p.D396H | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV67704405; called by muse, mutect2, varscan2
- OBSCN | c.3405G>T p.Q1135H | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV52798646; called by muse, mutect2, varscan2
- OBSCN | c.11315G>T p.R3772L | Missense Mutation (SNP) | VAF 59/289 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV52798673; called by muse, mutect2, varscan2
- OBSCN | c.14999G>T p.G5000V | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV52786737, COSV52798712; called by muse, mutect2, varscan2
- OCA2 | c.2272G>T p.D758Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62341806, COSV62358805; called by muse, mutect2, varscan2
- OLFML2B | c.1901C>A p.P634Q | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54198315; called by muse, mutect2, varscan2
- OPCML | c.830G>C p.R277P | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.362); catalogued as COSV59407859, COSV59435867; called by muse, mutect2, varscan2
- OPN1LW | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 72/774 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.084); catalogued as rs1166314366, COSV64049476; called by muse, mutect2
- OPN1LW | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 84/767 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV64049301, COSV64049516; called by muse, mutect2, varscan2
- OR10A5 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55054976; called by muse, mutect2, varscan2
- OR10AG1 | c.742A>T p.I248F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV56633826; called by muse, mutect2, varscan2
- OR10G7 | c.430G>C p.A144P | Missense Mutation (SNP) | VAF 91/239 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100390111, COSV57867904; called by muse, mutect2, varscan2
- OR10G8 | c.538G>C p.A180P | Missense Mutation (SNP) | VAF 101/267 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV70908536, COSV70908940; called by muse, mutect2, varscan2
- OR10P1 | c.236C>G p.P79R | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59007763; called by muse, mutect2, varscan2
- OR11A1 | c.500T>A p.L167Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65821228; called by muse, mutect2, varscan2
- OR11H4 | c.526C>A p.L176I | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV59560569; called by muse, mutect2, varscan2
- OR11H6 | c.733T>A p.C245S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV59644641; called by muse, mutect2, varscan2
- OR13C4 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52927673; called by muse, mutect2, varscan2
- OR1E2 | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.226); catalogued as COSV50265897; called by muse, mutect2, varscan2
- OR1I1 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 53/75 reads (71%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.446); catalogued as COSV52918545; called by muse, mutect2, varscan2
- OR2C3 | c.307T>A p.Y103N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV63575612; called by muse, mutect2, varscan2
- OR2L8 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61727524; called by muse, mutect2
- OR2M2 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 85/420 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as COSV62897737, COSV62898876; called by muse, mutect2, varscan2
- OR2M4 | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV60707731, COSV60708912; called by muse, mutect2
- OR2M5 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 130/358 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV63546657; called by muse, mutect2, varscan2
- OR2T27 | c.23T>A p.V8E | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV61282849; called by muse, mutect2, varscan2
- OR4C6 | c.312C>A p.F104L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.079); catalogued as COSV58605077; called by muse, mutect2, varscan2
- OR4D10 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV73260121; called by muse, mutect2, varscan2
- OR4K13 | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV59860177; called by muse, mutect2, varscan2
- OR4M1 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 70/367 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs569092650, COSV60060206, COSV60062519; called by muse, mutect2, varscan2
- OR51A7 | c.412A>T p.S138C | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as COSV63788666; called by muse, mutect2, varscan2
- OR51B4 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66517335, COSV66517455; called by muse, mutect2, varscan2
- OR51D1 | c.963A>T p.Q321H | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV62914444; called by muse, mutect2, varscan2
- OR51E1 | c.419C>A p.T140K | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67810461, COSV67810970; called by muse, mutect2, varscan2
- OR51E2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV67807951; called by muse, varscan2
- OR52B4 | c.296G>T p.C99F | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68769224; called by muse, mutect2, varscan2
- OR52E2 | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV100384740, COSV58613001; called by muse, mutect2, varscan2
- OR52E4 | c.406A>G p.M136V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV57625468; called by muse, mutect2, varscan2
- OR56A1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV57363218; called by muse, mutect2, varscan2
- OR5D13 | c.380C>A p.A127E | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1481160476, COSV62333523, COSV62334516; called by muse, mutect2
- OR5I1 | c.95T>A p.M32K | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV56888095; called by muse, mutect2, varscan2
- OR5L1 | c.125A>T p.N42I | Missense Mutation (SNP) | VAF 92/349 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61734674; called by muse, mutect2, varscan2
- OR5M11 | c.811A>G p.K271E | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV73141937; called by muse, mutect2, varscan2
- OR5M3 | c.289G>C p.V97L | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as COSV56567791; called by muse, mutect2, varscan2
- OR5W2 | c.772A>T p.M258L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as COSV60616474; called by muse, mutect2, varscan2
- OR6A2 | c.824C>G p.T275S | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.079); catalogued as COSV60265412; called by muse, mutect2, varscan2
- OR6N2 | c.20C>A p.S7* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as COSV59412184; called by muse, mutect2, varscan2
- OR6V1 | c.530G>T p.C177F | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69237503; called by muse, varscan2
- OR8A1 | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as COSV52507903, COSV52509280; called by muse, mutect2, varscan2
- OR8K1 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as COSV54402414, COSV54403507; called by muse, mutect2, varscan2
- OR8K5 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as COSV57887809; called by muse, mutect2, varscan2
- OR9A2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV63306889; called by muse, mutect2, varscan2
843 further variants in this file (485 protein-altering or splice-affecting, 325 silent, 33 other) are not listed here.
